Somatic mutation profile of tumor specimen C3L-00622-01 (aliquot CPT0081360007_1) from CPTAC case C3L-00622, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Age at diagnosis: 72.9 years (26,616 days).
Specimen C3L-00622-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df0ab0cc-fe6a-43dc-a105-dc96b35f023e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00622-31 (Blood Derived Normal), aliquot CPT0081400002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de60ae56-d9f0-4d84-929c-151348068f08

The open-access MAF lists 39 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 9, Intron 3, Splice Site 1, 5'UTR 1, 3'UTR 1, Splice Region 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 58/542 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 22/358 reads (6%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2
- GCGR | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 42/503 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1474100584; called by muse, mutect2
- KCNG1 | c.1271C>T p.T424M | Missense Mutation (SNP) | VAF 30/332 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65367890; called by muse, mutect2
- KIRREL2 | c.1723C>T p.R575W | Missense Mutation (SNP) | VAF 27/341 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as rs753993342; called by muse, mutect2
- MINK1 | c.2965G>A p.V989M | Missense Mutation (SNP) | VAF 53/464 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs200254448; called by muse, mutect2, varscan2
- PCDHB3 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 157/1899 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.049); catalogued as rs782605641, COSV50569302; called by muse, mutect2
- PRAMEF10 | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 78/1306 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1446723059; called by muse, mutect2
- RYR2 | c.1354G>C p.V452L | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.631); catalogued as COSV63701124; called by muse, mutect2
- ACSBG2 | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 90/849 reads (11%) | called by muse, mutect2
- ADAMTS9 | c.3741G>T p.W1247C | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP7A1 | c.1297T>C p.Y433H | Missense Mutation (SNP) | VAF 36/507 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- EEF2 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 46/576 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2
- GALNT2 | c.1430G>A p.G477E | Missense Mutation (SNP) | VAF 31/269 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR137C | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 52/570 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); called by muse, mutect2
- KATNIP | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 73/774 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2
- OR2L2 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.048); called by muse, mutect2
- PACSIN1 | c.847G>C p.D283H | Missense Mutation (SNP) | VAF 30/349 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PIK3R6 | c.889T>G p.W297G | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- PROX1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 29/298 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- S100A14 | c.247A>T p.S83C | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.308); called by muse, mutect2
- SLC29A2 | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 74/1090 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VWDE | c.3983-2A>T p.X1328_splice | Splice Site (SNP) | VAF 26/224 reads (12%) | called by muse, mutect2, varscan2
- WDR46 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 27/295 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.03); called by muse, mutect2
- DDHD1 | c.1699A>C p.R567= (on ENST00000323669; = p.R764= on NM_030637.3) | Silent (SNP) | VAF 31/240 reads (13%) | called by muse, mutect2, varscan2
- FABP12 | c.66G>A p.K22= | Silent (SNP) | VAF 26/449 reads (6%) | called by muse, mutect2
- FRAS1 | c.3357G>A p.K1119= | Silent (SNP) | VAF 42/590 reads (7%) | called by muse, mutect2
- GRID1 | c.219C>T p.F73= | Silent (SNP) | VAF 29/208 reads (14%) | called by muse, varscan2
- HS1BP3 | c.459G>A p.L153= | Silent (SNP) | VAF 67/482 reads (14%) | called by muse, mutect2, varscan2
- PCDHGB2 | c.600G>A p.L200= | Silent (SNP) | VAF 31/462 reads (7%) | called by muse, mutect2
- PDCD11 | c.2034G>A p.L678= | Silent (SNP) | VAF 36/482 reads (7%) | called by muse, mutect2
- SLC45A4 | c.1893C>T p.I631= (on ENST00000517878 / NM_001286646.2; = p.I580= on NM_001080431.2) | Silent (SNP) | VAF 75/886 reads (8%) | catalogued as rs202082870; called by muse, mutect2
- VEPH1 | c.1561T>C p.L521= | Silent (SNP) | VAF 40/348 reads (11%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.*50C>G | 3'UTR (SNP) | VAF 102/1142 reads (9%) | called by muse, mutect2
- AL353804.4 | chrX:73825322 G>T | 5'Flank (SNP) | VAF 27/140 reads (19%) | called by muse, mutect2, varscan2
- CACNA1A | c.5547-1230G>A | Intron (SNP) | VAF 14/210 reads (7%) | catalogued as rs1246077018, COSV100800227, COSV64214551; called by muse, mutect2
- SAE1 | c.98+27C>T | Intron (SNP) | VAF 14/132 reads (11%) | catalogued as rs879743914; called by mutect2, varscan2
- TTC21B | c.262+44A>C | Intron (SNP) | VAF 25/200 reads (13%) | catalogued as rs1394360183; called by muse, varscan2
- ZNF783 | c.-11C>T | 5'UTR (SNP) | VAF 34/339 reads (10%) | called by muse, mutect2, varscan2
